Somatic mutation profile of tumor specimen TARGET-20-PASTZD-09A (aliquot TARGET-20-PASTZD-09A-01D) from TARGET case TARGET-20-PASTZD, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.2 years (804 days).
Specimen TARGET-20-PASTZD-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d19abae-0da3-4f4a-83e0-caa780b42699.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASTZD-14A (Bone Marrow Normal), aliquot TARGET-20-PASTZD-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61120e3f-c081-4598-a2a7-3c56f1c9df97

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2517T>A p.D839E | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.421); catalogued as COSV54045931; called by muse, mutect2, varscan2
- MYCBP2 | c.6154C>T p.L2052F (on ENST00000357337; = p.L2090F on NM_015057.5) | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.351); called by muse, mutect2, varscan2
